TCGA case TCGA-10-0931 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e07a61e2-bcd2-4a96-80df-97e04aafbd32

Demographics
Sex at birth: female; Race: white; Age at index: 44 years; Vital status: Dead; Days to death: 1,000 days (2.7 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 44.5 years (16,262 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 124 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 124 days; Number of cycles: 6; Treatment dose: 2,430 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 124 days; Number of cycles: 6; Treatment dose: 2,268 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease; Days to treatment start: 335 days; Days to treatment end: 383 days (1.0 years); Treatment dose: 1,880 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 386 days (1.1 years); Days to treatment end: 509 days (1.4 years); Number of cycles: 6; Treatment dose: 3,240 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 386 days (1.1 years); Days to treatment end: 509 days (1.4 years); Number of cycles: 6; Treatment dose: 1,632 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 538 days (1.5 years); Days to treatment end: 666 days (1.8 years); Number of cycles: 8; Treatment dose: 1,840 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 538 days (1.5 years); Days to treatment end: 666 days (1.8 years); Number of cycles: 6; Treatment dose: 420 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 538 days (1.5 years); Days to treatment end: 666 days (1.8 years); Number of cycles: 4; Treatment dose: 440 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Gefitinib; Initial disease status: Recurrent Disease; Days to treatment start: 792 days (2.2 years); Days to treatment end: 848 days (2.3 years); Treatment dose: 14,000 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 792 days (2.2 years); Days to treatment end: 848 days (2.3 years); Number of cycles: 3; Treatment dose: 24 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 876 days (2.4 years); Days to treatment end: 932 days (2.6 years); Number of cycles: 3; Treatment dose: 231 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 45.3 years (16,562 days); Days to diagnosis: 300 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 300 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 300 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 982 days (2.7 years); Disease response: With Tumor.
- Days to follow up: 1,000 days (2.7 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-10-0931-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.5; Intermediate dimension: 0.5; Shortest dimension: 0.5.
  Slide TCGA-10-0931-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-10-0931-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-10-0931-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Herceptin.
- Drug treatment 4: Pharmaceutical therapy drug name: Irressa.
- Drug treatment 6: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 8: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 9: Pharmaceutical therapy drug name: Doxil.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,000 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,000 days; disease-free interval: event (new tumor event after initially disease-free), 300 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 300 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-10-0931-01A-01D-0399-01): tumor purity 0.9, ploidy 1.99, whole-genome doublings 0.
